Somatic mutation profile of tumor specimen TCGA-32-1991-01A (aliquot TCGA-32-1991-01A-01D-1353-08) from TCGA case TCGA-32-1991, project TCGA-GBM (Glioblastoma Multiforme). Sex at birth: male; Vital status: Dead; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 60.3 years (22,021 days).
Specimen TCGA-32-1991-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 21b9f3ba-edcc-4640-9ddd-e8f60ec456f3.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-32-1991-10C (Blood Derived Normal), aliquot TCGA-32-1991-10C-01D-1353-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/10c42f7f-29aa-4e20-ba4a-b19d807ef40e

The open-access MAF lists 39 somatic variants for this specimen: 29 protein-altering or splice-affecting, 10 silent.
By variant classification: Missense Mutation 23, Silent 10, Nonsense Mutation 3, Splice Site 2, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PIK3R1 | c.1689_1691del p.M563_N564delinsI (on ENST00000521381 / NM_181523.3; = p.M293_N294delinsI on NM_181504.4) | In Frame Del (DEL) | VAF 104/297 reads (35%) | hotspot (GDC flag); called by mutect2, pindel, varscan2
- ARHGAP44 | c.1976C>A p.P659H | Missense Mutation (SNP) | VAF 37/104 reads (36%) | SIFT deleterious, low confidence (0.04); PolyPhen possibly damaging (0.754); catalogued as COSV52404559; called by muse, mutect2, varscan2
- CFH | c.2835G>T p.M945I | Missense Mutation (SNP) | VAF 135/312 reads (43%) | SIFT tolerated (0.13); PolyPhen benign (0.096); catalogued as COSV66414698; called by muse, mutect2, varscan2
- CGN | c.249G>T p.K83N | Missense Mutation (SNP) | VAF 48/137 reads (35%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.998); catalogued as COSV54974562; called by muse, mutect2, varscan2
- CILP2 | c.1639G>A p.V547M | Missense Mutation (SNP) | VAF 103/242 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV52274272, COSV99364980; called by muse, mutect2, varscan2
- DCTN4 | c.207-1G>T p.X69_splice | Splice Site (SNP) | VAF 36/75 reads (48%) | catalogued as COSV69783236, COSV99073692; called by muse, mutect2, varscan2
- DRD5 | c.430A>T p.R144W | Missense Mutation (SNP) | VAF 32/78 reads (41%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.937); catalogued as COSV58580916, COSV58580984; called by muse, mutect2, varscan2
- ERCC6L2 | c.2008G>T p.G670* | Nonsense Mutation (SNP) | VAF 95/247 reads (38%) | catalogued as COSV56634856; called by muse, mutect2, varscan2
- GOLGA6L22 | c.114G>T p.K38N | Missense Mutation (SNP) | VAF 42/227 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.982); catalogued as rs1398617171; called by muse, mutect2, varscan2
- GRIN2B | c.514G>A p.V172I | Missense Mutation (SNP) | VAF 77/245 reads (31%) | SIFT tolerated (0.39); PolyPhen possibly damaging (0.726); catalogued as rs201377003, COSV74205072; ClinVar: likely benign; called by muse, mutect2, varscan2
- INPP5B | c.1675A>G p.K559E (on ENST00000373023; = p.K479E on NM_005540.3 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 79/209 reads (38%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.472); catalogued as COSV65963405; called by muse, mutect2, varscan2
- KCNK3 | c.449G>A p.R150Q | Missense Mutation (SNP) | VAF 56/185 reads (30%) | SIFT tolerated (0.1); PolyPhen benign (0.044); catalogued as rs1321028147, COSV57193967; called by muse, mutect2, varscan2
- MAGEA11 | c.59A>C p.K20T | Missense Mutation (SNP) | VAF 102/136 reads (75%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.044); catalogued as COSV60759305; called by muse, mutect2, varscan2
- NANOG | c.174G>A p.M58I | Missense Mutation (SNP) | VAF 210/557 reads (38%) | SIFT tolerated (0.23); PolyPhen benign (0.071); catalogued as COSV57552782; called by muse, mutect2, varscan2
- NEUROD2 | c.572C>T p.T191I | Missense Mutation (SNP) | VAF 38/79 reads (48%) | SIFT deleterious (0); PolyPhen possibly damaging (0.528); catalogued as COSV56911977; called by muse, mutect2, varscan2
- NLRP2 | c.1639A>T p.N547Y | Missense Mutation (SNP) | VAF 71/200 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV54761624; called by muse, mutect2, varscan2
- OR2M5 | c.92T>C p.V31A | Missense Mutation (SNP) | VAF 281/715 reads (39%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.701); catalogued as COSV63547218; called by muse, mutect2, varscan2
- PIGR | c.1235G>A p.R412H | Missense Mutation (SNP) | VAF 14/52 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs767107680, COSV62905242; called by muse, mutect2
- PRKCG | c.614G>A p.R205Q | Missense Mutation (SNP) | VAF 39/250 reads (16%) | SIFT tolerated (0.07); PolyPhen benign (0.01); catalogued as rs762399754, COSV54731250; called by muse, mutect2, varscan2
- PSG3 | c.959G>A p.R320H | Missense Mutation (SNP) | VAF 120/382 reads (31%) | SIFT tolerated (0.25); PolyPhen benign (0.009); catalogued as rs766220350, COSV59507268; called by muse, varscan2
- PTEN | c.661A>T p.K221* | Nonsense Mutation (SNP) | VAF 37/207 reads (18%) | catalogued as rs1554825174, COSV64292017; called by muse, mutect2, varscan2
- RNF133 | c.499A>C p.I167L | Missense Mutation (SNP) | VAF 177/591 reads (30%) | SIFT tolerated (0.06); PolyPhen benign (0.22); catalogued as COSV57390137; called by muse, mutect2, varscan2
- RTL9 | c.409G>A p.V137I | Missense Mutation (SNP) | VAF 162/199 reads (81%) | SIFT tolerated (0.07); PolyPhen benign (0.015); catalogued as rs1408211500, COSV71826629; called by muse, mutect2, varscan2
- RUVBL2 | c.445C>T p.R149* | Nonsense Mutation (SNP) | VAF 70/170 reads (41%) | catalogued as COSV55487738; called by muse, mutect2, varscan2
- RYR3 | c.4592T>A p.M1531K | Missense Mutation (SNP) | VAF 14/26 reads (54%) | SIFT deleterious (0); PolyPhen possibly damaging (0.603); catalogued as COSV66811365; called by muse, mutect2
- SEPSECS | c.1211+1G>A p.X404_splice | Splice Site (SNP) | VAF 21/52 reads (40%) | catalogued as rs781642082, COSV57208149; called by muse, mutect2, varscan2
- ZFAND3 | c.443G>C p.R148P | Missense Mutation (SNP) | VAF 69/176 reads (39%) | SIFT tolerated (0.16); PolyPhen benign (0.246); catalogued as COSV54735556, COSV99765248; called by muse, mutect2, varscan2
- ZNF516 | c.3071C>T p.A1024V | Missense Mutation (SNP) | VAF 45/81 reads (56%) | SIFT tolerated (0.16); PolyPhen benign (0); catalogued as rs761660108, COSV71587762; called by muse, mutect2, varscan2
- ZNF622 | c.1178A>T p.H393L | Missense Mutation (SNP) | VAF 156/409 reads (38%) | SIFT deleterious (0); PolyPhen benign (0.312); catalogued as rs767955612, COSV58075537; called by muse, mutect2, varscan2
- ABL2 | c.2733G>A p.P911= (on ENST00000502732 / NM_007314.4; = p.P896= on NM_005158.5) | Silent (SNP) | VAF 31/111 reads (28%) | catalogued as rs569106848, COSV61021679; called by muse, mutect2, varscan2
- CHRFAM7A | c.417G>A p.R139= | Silent (SNP) | VAF 77/228 reads (34%) | catalogued as COSV55398176; called by muse, mutect2, varscan2
- NKX3-1 | c.678G>A p.V226= | Silent (SNP) | VAF 66/171 reads (39%) | catalogued as COSV66512973; called by muse, mutect2, varscan2
- OR8G1 | c.69C>T p.L23= | Silent (SNP) | VAF 64/161 reads (40%) | catalogued as COSV100422198; called by muse, mutect2, varscan2
- PLEKHM3 | c.1368T>C p.N456= | Silent (SNP) | VAF 50/127 reads (39%) | catalogued as rs768218438, COSV66819159; called by muse, mutect2, varscan2
- SLC22A11 | c.1425G>A p.G475= | Silent (SNP) | VAF 98/301 reads (33%) | catalogued as COSV57255409; called by muse, mutect2, varscan2
- SWT1 | c.831A>G p.L277= | Silent (SNP) | VAF 137/340 reads (40%) | catalogued as COSV62260061; called by muse, mutect2, varscan2
- UBR3 | c.3792G>A p.G1264= | Silent (SNP) | VAF 74/213 reads (35%) | catalogued as COSV55863032; called by muse, mutect2, varscan2
- VPS26B | c.372G>T p.V124= | Silent (SNP) | VAF 70/173 reads (40%) | catalogued as COSV55546910; called by muse, mutect2, varscan2
- WDR72 | c.1098T>C p.P366= | Silent (SNP) | VAF 69/189 reads (37%) | catalogued as COSV64754977; called by muse, mutect2, varscan2
